Somatic mutation profile of tumor specimen MP2PRT-PAVUIG-TMP1-A (aliquot MP2PRT-PAVUIG-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVUIG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,156 days).
Specimen MP2PRT-PAVUIG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) caee71b1-996a-4675-9924-c33f9cc30589.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVUIG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVUIG-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2cdd86e-41a3-48f5-8724-c3f2973141c6

The open-access MAF lists 29 somatic variants for this specimen: 17 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 10, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKNAD1 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 14/502 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.539); catalogued as COSV100645792; called by muse, mutect2
- ANKRD49 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1194598347; called by muse, mutect2, varscan2
- AP3S1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as rs757919211; called by muse, mutect2
- C16orf89 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 127/356 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs372507235; called by muse, mutect2, varscan2
- CRB1 | c.1531G>T p.A511S | Missense Mutation (SNP) | VAF 107/337 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV100957765; called by muse, mutect2, varscan2
- DGKB | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51819170; called by muse, mutect2, varscan2
- KMT2C | c.12280A>G p.I4094V | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); catalogued as rs775955880; called by muse, mutect2, varscan2
- LTA4H | c.719C>G p.S240C | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.394); catalogued as rs765372848; called by muse, mutect2, varscan2
- PRKAA1 | c.1284C>G p.I428M | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1207503865; called by muse, mutect2
- TSBP1 | c.1458G>C p.E486D (on ENST00000617061; = p.E491D on NM_006781.5) | Missense Mutation (SNP) | VAF 13/389 reads (3%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as COSV66658935; called by muse, mutect2
- VGLL2 | c.93T>A p.Y31* | Nonsense Mutation (SNP) | VAF 64/284 reads (23%) | catalogued as COSV100409805, COSV58309990; called by muse, mutect2, varscan2
- ACAN | c.2678G>C p.G893A | Missense Mutation (SNP) | VAF 24/532 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- BRINP1 | c.179G>C p.R60T | Missense Mutation (SNP) | VAF 63/295 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- CADPS | c.2419G>C p.E807Q | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2
- CFAP221 | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- KRAS | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF608 | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 68/320 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- C1orf50 | c.168C>T p.L56= | Silent (SNP) | VAF 107/595 reads (18%) | called by muse, mutect2, varscan2
- CT83 | c.34C>T p.L12= | Silent (SNP) | VAF 19/208 reads (9%) | catalogued as rs782743164; called by muse, mutect2
- DRD3 | c.1134C>T p.L378= | Silent (SNP) | VAF 73/350 reads (21%) | catalogued as COSV55682748; called by muse, mutect2, varscan2
- FREM2 | c.1515G>A p.K505= | Silent (SNP) | VAF 36/508 reads (7%) | called by muse, mutect2
- MFSD1 | c.993C>T p.I331= | Silent (SNP) | VAF 73/354 reads (21%) | catalogued as COSV99963980; called by muse, mutect2, varscan2
- PAX7 | c.1107G>A p.A369= | Silent (SNP) | VAF 27/667 reads (4%) | catalogued as COSV64752287; called by muse, mutect2
- PCDH15 | c.2683C>T p.L895= | Silent (SNP) | VAF 12/327 reads (4%) | called by muse, mutect2
- PCDHA11 | c.1299T>G p.S433= | Silent (SNP) | VAF 135/399 reads (34%) | catalogued as rs782585618; called by muse, mutect2, varscan2
- SHROOM2 | c.1641G>A p.A547= | Silent (SNP) | VAF 139/343 reads (41%) | catalogued as rs754693285; called by muse, mutect2, varscan2
- TMEM135 | c.345C>G p.L115= | Silent (SNP) | VAF 16/237 reads (7%) | called by muse, mutect2
- C8orf34 | c.607+30C>G | Intron (SNP) | VAF 9/234 reads (4%) | called by muse, mutect2
- FER | c.1237-21411C>G | Intron (SNP) | VAF 50/229 reads (22%) | called by muse, mutect2, varscan2
